Somatic mutation profile of tumor specimen TARGET-10-PARMFF-09A (aliquot TARGET-10-PARMFF-09A-01D) from TARGET case TARGET-10-PARMFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,039 days).
Specimen TARGET-10-PARMFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 194b6cbe-927f-442b-91be-5d92552e5f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMFF-14A (Bone Marrow Normal), aliquot TARGET-10-PARMFF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08f3c5e9-9aa2-4c91-9eb2-484361044100

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, 3'UTR 4, Nonsense Mutation 3, Silent 2, Splice Site 2, 5'Flank 1, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 37/191 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 6/117 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- RXYLT1 | c.743+1G>A p.X248_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | catalogued as rs778174763, COSV54170124, COSV54170575; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM11 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV52350700; called by muse, mutect2, varscan2
- CCDC168 | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.634); catalogued as COSV70556475; called by muse, mutect2, varscan2
- CDC42 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1240303878; called by muse, mutect2, varscan2
- CYP27C1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as rs547196058, COSV58869024; called by muse, mutect2, varscan2
- FBXW7 | c.664C>T p.R222* (on ENST00000281708 / NM_001349798.2; = p.R142* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | catalogued as rs920052554, COSV55897378; called by muse, mutect2, varscan2
- FBXW7 | c.501+2T>A p.X167_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV55973046; called by muse, mutect2, varscan2
- IL16 | c.1399A>G p.R467G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1406258526, COSV57269825; called by muse, mutect2, varscan2
- ITSN2 | c.2927C>G p.T976S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61955319; called by muse, mutect2, varscan2
- KAT5 | c.840+7G>A | Splice Region (SNP) | VAF 47/210 reads (22%) | catalogued as COSV57730756; called by muse, mutect2, varscan2
- KIAA1614 | c.3388G>C p.G1130R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201859148, COSV62551465, COSV62552100; called by muse, mutect2, varscan2
- LINGO2 | c.1807A>C p.M603L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58066090; called by muse, mutect2, varscan2
- MSN | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV64303362; called by muse, mutect2, varscan2
- OTOG | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867715728, COSV61131624; called by muse, mutect2, varscan2
- PDZRN4 | c.1687C>T p.R563* (on ENST00000402685 / NM_001164595.2; = p.R305* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as rs150680549, COSV54203393; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- TELO2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs752263174, COSV51982154; called by muse, mutect2, varscan2
- ZNF219 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV53885872; called by muse, mutect2, varscan2
- ETFA | c.459dup p.L154Sfs*7 | Frame Shift Ins (INS) | VAF 26/172 reads (15%) | called by mutect2, pindel, varscan2
- EXOC6 | c.2109T>C p.S703= | Silent (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2, varscan2
- PGM1 | c.693G>A p.P231= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs538147286, COSV64300928; called by muse, mutect2, varscan2
- ASB10 | chr7:151187482 C>T | 5'Flank (SNP) | VAF 17/90 reads (19%) | catalogued as rs745928628, COSV52001861; called by muse, mutect2, varscan2
- C7 | c.*19C>T | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- LTO1 | c.346-1136G>A | Intron (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- OR51G2 | c.*34A>G | 3'UTR (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- PSMA8 | c.*59G>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- ZNF395 | c.*6G>A | 3'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
